Somatic mutation profile of tumor specimen TCGA-SX-A71U-01A (aliquot TCGA-SX-A71U-01A-12D-A33Q-10) from TCGA case TCGA-SX-A71U, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 57.7 years (21,079 days).
Specimen TCGA-SX-A71U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a6f0380-6c6e-4e08-9db3-1d821db6a62d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SX-A71U-10A (Blood Derived Normal), aliquot TCGA-SX-A71U-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bb53143-bdd5-4316-9cb5-d1b25b8c07e9

The open-access MAF lists 109 somatic variants for this specimen: 80 protein-altering or splice-affecting, 25 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 25, Nonsense Mutation 8, Frame Shift Del 7, Splice Site 5, In Frame Del 3, Frame Shift Ins 3, Splice Region 2, Intron 2, Translation Start Site 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM32 | c.1433T>G p.I478S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV101165178; called by muse, mutect2, varscan2
- ADCY10 | c.297T>A p.D99E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100896462; called by muse, mutect2, varscan2
- ADK | c.34A>C p.K12Q | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.646); catalogued as COSV99691285; called by muse, mutect2, varscan2
- ARRDC5 | c.722G>A p.R241Q (on ENST00000381781; = p.R227Q on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.046); catalogued as rs899677075, COSV101108049; called by muse, mutect2, varscan2
- ATF7IP | c.1097A>G p.E366G | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV99661029; called by muse, mutect2, varscan2
- ATG2B | c.3164T>C p.L1055P | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV100737610; called by muse, mutect2, varscan2
- C9orf152 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV101272363; called by muse, mutect2, varscan2
- CCSER2 | c.1812T>G p.H604Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99825304; called by muse, mutect2, varscan2
- CFAP57 | c.644C>A p.T215N | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV100993724; called by muse, mutect2, varscan2
- CNTN6 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.1); catalogued as COSV100609654; called by muse, mutect2, varscan2
- COL4A2 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100847043, COSV64631409; called by muse, mutect2
- CXorf38 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 65/84 reads (77%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100010156; called by muse, mutect2, varscan2
- DDX23 | c.2225C>A p.A742D | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99974575; called by muse, mutect2, varscan2
- DNPEP | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99815000; called by muse, mutect2, varscan2
- EID1 | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100194036; called by muse, mutect2, varscan2
- EPHA10 | c.1494T>A p.G498= | Splice Region (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100360810, COSV57626757; called by muse, mutect2, varscan2
- ETFDH | c.1576G>T p.G526C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306659; called by muse, mutect2, varscan2
- FANCL | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99287139; called by muse, mutect2, varscan2
- GALNT7 | c.694A>C p.K232Q | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV99396741; called by muse, mutect2, varscan2
- GTF2I | c.1162C>A p.P388T (on ENST00000573035 / NM_032999.4; = p.P347T on NM_001518.5) | Missense Mutation (SNP) | VAF 85/361 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.582); catalogued as COSV100259347; called by muse, mutect2, varscan2
- H2BC3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs757666983, COSV100778222; called by muse, mutect2, varscan2
- HGFAC | c.1083C>A p.Y361* | Nonsense Mutation (SNP) | VAF 35/85 reads (41%) | catalogued as COSV101237720; called by muse, mutect2, varscan2
- HMCN1 | c.13232A>C p.N4411T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.995); catalogued as COSV99622296; called by muse, mutect2, varscan2
- HMGCS2 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV101024651; called by muse, mutect2, varscan2
- IGF2BP3 | c.1641+2C>T p.X547_splice | Splice Site (SNP) | VAF 103/216 reads (48%) | catalogued as COSV99324819; called by muse, mutect2, varscan2
- IGF2BP3 | c.1641+1G>A p.X547_splice | Splice Site (SNP) | VAF 105/216 reads (49%) | catalogued as COSV99324820; called by muse, mutect2, varscan2
- IK | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 102/265 reads (38%) | catalogued as COSV101341729; called by muse, mutect2, varscan2
- KDM1B | c.373C>G p.P125A | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.54); catalogued as COSV99923766; called by muse, mutect2, varscan2
- KLHDC7A | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV68769743, COSV68770451; called by muse, mutect2, varscan2
- KLHL8 | c.1319G>T p.W440L | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99911171; called by muse, mutect2, varscan2
- KMT2C | c.10588T>A p.S3530T | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV100064496; called by muse, mutect2, varscan2
- MAS1 | c.759G>T p.E253D | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.186); catalogued as COSV99396745; called by muse, mutect2, varscan2
- MYO5C | c.3308T>C p.M1103T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.269); catalogued as COSV99953858; called by muse, mutect2, varscan2
- NEDD4L | c.2410A>T p.K804* (on ENST00000400345 / NM_001144967.3; = p.K784* on NM_015277.6) | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as COSV99893022; called by muse, mutect2, varscan2
- NFAM1 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100215747; called by muse, mutect2, varscan2
- PCF11 | c.1768A>G p.S590G | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100019575, COSV53527525, COSV99036186; called by muse, mutect2, varscan2
- PDZRN4 | c.2669A>C p.K890T (on ENST00000402685 / NM_001164595.2; = p.K632T on NM_013377.4) | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100113272; called by muse, mutect2, varscan2
- PEAR1 | c.533G>T p.C178F | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99440391, COSV99442448; called by muse, mutect2, varscan2
- PMS1 | c.812A>C p.D271A | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV100575386, COSV59716881; called by muse, mutect2
- PMS1 | c.814A>T p.I272F | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100575387; called by muse, mutect2
- PPIP5K2 | c.2417A>G p.Y806C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100383318; called by muse, mutect2, varscan2
- PRRC2C | c.5132G>T p.W1711L (on ENST00000367742; = p.W1709L on NM_015172.4) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100144464, COSV58905512; called by muse, mutect2, varscan2
- RAD51B | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); catalogued as rs200741476; called by muse, mutect2, varscan2
- RBM47 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs1292312499, COSV99919921; called by muse, mutect2, varscan2
- RNF181 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV57818628; called by muse, mutect2, varscan2
- RNF181 | c.260A>C p.E87A | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV100110423; called by muse, mutect2, varscan2
- ROBO2 | c.2237T>C p.L746P | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV100163237; called by muse, mutect2, varscan2
- SENP7 | c.395C>A p.S132* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100052060; called by muse, mutect2
- SLC22A7 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs781251888, COSV101000735, COSV65356964; called by muse, mutect2, varscan2
- SLC38A2 | c.1304G>C p.R435T | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as COSV99873653; called by muse, mutect2, varscan2
- SNRNP40 | c.772A>T p.T258S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as COSV99744943; called by muse, mutect2, varscan2
- SPAG11B | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 146/506 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV99872649; called by muse, mutect2
- SPIRE2 | c.1591G>A p.V531M | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773095677, COSV100988675; called by muse, mutect2, varscan2
- SRRT | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as COSV100729949; called by muse, varscan2
- STAT1 | c.157G>C p.A53P | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100738379; called by muse, mutect2, varscan2
- TADA1 | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.405); catalogued as COSV100902269; called by muse, mutect2, varscan2
- TEX19 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 34/86 reads (40%) | catalogued as COSV100330966; called by muse, mutect2, varscan2
- TMCC2 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100404880; called by muse, mutect2, varscan2
- TSPYL6 | c.1061T>A p.F354Y | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100336170; called by muse, mutect2, varscan2
- TTN | c.79096A>T p.T26366S (on ENST00000591111; = p.T18942S on NM_003319.4) | Missense Mutation (SNP) | VAF 20/81 reads (25%) | PolyPhen possibly damaging (0.562); catalogued as COSV100588749; called by muse, mutect2, varscan2
- VAMP1 | c.289-1G>A p.X97_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as COSV56946056, COSV99868842; called by muse, mutect2, varscan2
- ZNF22 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV53584698; called by muse, mutect2, varscan2
- ZNF251 | c.36G>A p.E12= | Splice Region (SNP) | VAF 37/76 reads (49%) | catalogued as COSV99478024; called by muse, mutect2, varscan2
- ZNF395 | c.1452G>C p.K484N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100733808, COSV100734063, COSV60428461; called by muse, mutect2, varscan2
- ZNF681 | c.670A>C p.K224Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV101267368; called by muse, mutect2, varscan2
- CFAP47 | c.2713+2dup p.X905_splice | Splice Site (INS) | VAF 23/32 reads (72%) | called by mutect2, varscan2
- DIP2C | c.983del p.G328Afs*10 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- EMC4 | c.293del p.P98Lfs*3 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- EZHIP | c.127_129del p.A43del | In Frame Del (DEL) | VAF 44/63 reads (70%) | called by pindel, varscan2
- HIPK1 | c.621_623del p.C207del | In Frame Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.5688del p.K1896Nfs*12 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by mutect2, pindel, varscan2
- KIAA0586 | c.4110dup p.D1371* (on ENST00000619416 / NM_001244190.2; = p.D1310* on NM_014749.5) | Frame Shift Ins (INS) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.14416dup p.T4806Nfs*13 | Frame Shift Ins (INS) | VAF 32/95 reads (34%) | called by mutect2, pindel, varscan2
- MED13L | c.5210dup p.D1738Gfs*2 | Frame Shift Ins (INS) | VAF 15/86 reads (17%) | called by mutect2, pindel, varscan2
- NEDD4 | c.1212del p.K405Sfs*25 | Frame Shift Del (DEL) | VAF 33/102 reads (32%) | called by mutect2, pindel, varscan2
- NIPBL | c.5603_5620del p.V1868_R1873del | In Frame Del (DEL) | VAF 38/180 reads (21%) | called by mutect2, pindel, varscan2
- NRN1 | c.269_276del p.M90Kfs*83 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- NUP43 | c.589del p.I197Yfs*17 | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | called by mutect2, pindel, varscan2
- PPP6R3 | c.1740del p.F580Lfs*98 (on ENST00000393800 / NM_001352375.2; = p.F500Lfs*98 on NM_018312.5) | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- SORL1 | c.5240-8_5249del p.X1747_splice | Splice Site (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- ABCC5 | c.4239C>G p.V1413= | Silent (SNP) | VAF 53/150 reads (35%) | catalogued as COSV99656200; called by muse, mutect2, varscan2
- ACTR1B | c.468G>T p.V156= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100007891; called by muse, mutect2
- ARHGDIA | c.21A>C p.T7= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99482432; called by muse, mutect2, varscan2
- ARPC5 | c.21G>T p.S7= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV99664672; called by muse, mutect2, varscan2
- CCDC170 | c.1272C>T p.N424= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV99498021; called by muse, mutect2, varscan2
- CPED1 | c.2946T>C p.Y982= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV100119679; called by muse, mutect2, varscan2
- DDO | c.396T>C p.F132= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as COSV100927793; called by muse, mutect2, varscan2
- DISP3 | c.207C>T p.T69= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV99606969; called by muse, mutect2, varscan2
- EHBP1 | c.1983A>G p.G661= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV99859672; called by muse, mutect2, varscan2
- ENTPD4 | c.276G>C p.V92= | Silent (SNP) | VAF 71/143 reads (50%) | catalogued as COSV100652465; called by muse, mutect2, varscan2
- FAM8A1 | c.603C>A p.G201= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99467155; called by muse, mutect2, varscan2
- FBXO10 | c.2818C>A p.R940= | Silent (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- HGS | c.1761C>A p.A587= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100230110; called by muse, mutect2, varscan2
- OR1L1 | c.825T>G p.V275= (on ENST00000373686; = p.V225= on NM_001005236.3) | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV100542046; called by muse, mutect2, varscan2
- PHYHD1 | c.570C>A p.I190= (on ENST00000372592 / NM_001100876.2; = p.S183Y on NM_174933.4) | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100454892; called by muse, mutect2, varscan2
- PLXNB1 | c.1449T>C p.A483= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV99601998; called by muse, mutect2, varscan2
- POLR1G | c.1281G>A p.K427= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as rs1360386294, COSV50004070, COSV99185216; called by muse, varscan2
- PPHLN1 | c.417T>C p.D139= | Silent (SNP) | VAF 102/189 reads (54%) | catalogued as COSV99871341; called by muse, mutect2, varscan2
- RANBP9 | c.1452A>G p.P484= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs774253321, COSV99163482; called by muse, mutect2, varscan2
- SLC19A3 | c.63A>G p.L21= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV99295551; called by muse, mutect2, varscan2
- TBC1D15 | c.252T>C p.G84= | Silent (SNP) | VAF 105/209 reads (50%) | catalogued as COSV100041244; called by muse, mutect2, varscan2
- TSPYL2 | c.465G>C p.A155= | Silent (SNP) | VAF 41/51 reads (80%) | catalogued as COSV100211960; called by muse, mutect2, varscan2
- TSSK6 | c.558C>A p.I186= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99388837; called by muse, varscan2
- UGT1A5 | c.651T>G p.P217= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV100529226; called by muse, mutect2, varscan2
- ZNF391 | c.618T>C p.T206= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV99772325; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1218dup | Intron (INS) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- DENND10P1 | n.1256G>T | RNA (SNP) | VAF 74/172 reads (43%) | called by muse, mutect2, varscan2
- GLS | c.1650+1145A>G | Intron (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100289630; called by muse, mutect2, varscan2
- PVRIG | chr7:100223658 G>A | 3'Flank (SNP) | VAF 87/386 reads (23%) | catalogued as COSV99443613; called by muse, mutect2, varscan2
